Somatic mutation profile of tumor specimen C3L-00898-02 (aliquot CPT0172200011) from CPTAC case C3L-00898, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.0 years (20,081 days).
Specimen C3L-00898-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eeac1981-662f-4556-8461-566c8e49f5d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00898-72 (Blood Derived Normal), aliquot CPT0172430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d698bf0-c46b-43be-939b-9c7d0bc7d338

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 4, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 120/392 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 24/386 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.48T>A p.Y16* | Nonsense Mutation (SNP) | VAF 122/443 reads (28%) | hotspot (GDC flag); catalogued as rs587782187, CM110154, COSV64288363, COSV64293151, COSV64295030; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 78/317 reads (25%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ATP2B2 | c.1996C>T p.R666C (on ENST00000352432; = p.R632C on NM_001683.5) | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660646; called by muse, mutect2
- C1QTNF6 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 57/444 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377228466; called by muse, mutect2, varscan2
- CLTCL1 | c.2923G>A p.V975I | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.983); catalogued as rs1555949430; called by muse, mutect2
- CTU1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 53/469 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV70292301; called by muse, mutect2, varscan2
- GRIN2A | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 30/571 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1489261681, COSV58032859, COSV58037182; ClinVar: not provided; called by muse, mutect2
- LIPE | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs747595020; called by muse, mutect2
- LYST | c.5784+1G>T p.X1928_splice | Splice Site (SNP) | VAF 39/188 reads (21%) | catalogued as COSV67711266; called by muse, mutect2, varscan2
- MYH6 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 23/476 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs767702815, COSV62453062; called by muse, mutect2
- OR10Q1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1218234729; called by muse, mutect2
- P2RY12 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1345420919; called by muse, mutect2, varscan2
- P2RY2 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1242698397; called by muse, mutect2, varscan2
- PCDHB8 | c.2147G>A p.R716K | Missense Mutation (SNP) | VAF 168/495 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs782608867, COSV50770071; called by muse, mutect2, varscan2
- PSME3 | c.95A>T p.N32I | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs768346900; called by muse, mutect2, varscan2
- SHANK1 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1390006492, COSV53256684; called by muse, mutect2, varscan2
- SI | c.2934A>T p.R978S | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs779890126; called by muse, mutect2
- ST3GAL5 | c.529G>A p.D177N (on ENST00000377332; = p.D217N on NM_003896.4) | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767789131, COSV60385231; called by muse, mutect2
- SYMPK | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780926621, COSV99841988; called by muse, mutect2
- TCIRG1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763667012, COSV99693495; called by muse, mutect2
- USP36 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1016299421; called by muse, mutect2
- WNT5B | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 51/210 reads (24%) | catalogued as rs906923865; called by muse, mutect2, varscan2
- ZNF611 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs761780084; called by muse, mutect2, varscan2
- ADGB | c.4880T>G p.L1627W | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ARID1A | c.6286del p.S2096Qfs*39 | Frame Shift Del (DEL) | VAF 71/272 reads (26%) | called by mutect2, pindel*, varscan2
- CCDC157 | c.1354C>G p.R452G | Missense Mutation (SNP) | VAF 78/369 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CCL13 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- CELSR3 | c.4901A>C p.D1634A | Missense Mutation (SNP) | VAF 94/396 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- DDX53 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- FAM120C | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 73/290 reads (25%) | called by muse, mutect2, varscan2
- MMS22L | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOA1 | c.665A>T p.D222V | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PHF3 | c.4519A>G p.I1507V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PJA1 | c.979G>A p.E327K (on ENST00000361478 / NM_145119.4; = p.E139K on NM_022368.5) | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.081); called by muse, mutect2
- PTEN | c.943dup p.Y315Lfs*10 | Frame Shift Ins (INS) | VAF 97/344 reads (28%) | called by mutect2, pindel, varscan2
- PUS7 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ACADL | c.90C>T p.S30= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as rs755556107, COSV52052109, COSV99285131; called by muse, mutect2
- CCNT1 | c.1977C>T p.D659= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as rs1438109050; called by muse, mutect2, varscan2
- CD14 | c.717C>A p.G239= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- CELSR2 | c.3681C>T p.F1227= | Silent (SNP) | VAF 20/333 reads (6%) | catalogued as rs375156778; called by muse, mutect2
- IGHD | c.1263C>T p.S421= | Silent (SNP) | VAF 98/394 reads (25%) | catalogued as rs1405136170; called by muse, mutect2, varscan2
- ITIH5 | c.2691C>T p.N897= | Silent (SNP) | VAF 40/493 reads (8%) | catalogued as rs767367042, COSV99903860; called by muse, mutect2
- KATNIP | c.1572G>C p.G524= | Silent (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- MUC5B | c.2031C>A p.G677= | Silent (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- MYH1 | c.2610C>T p.T870= | Silent (SNP) | VAF 108/543 reads (20%) | catalogued as rs1198526505, COSV99876448; called by muse, mutect2, varscan2
- PAFAH1B3 | c.468C>T p.N156= | Silent (SNP) | VAF 87/233 reads (37%) | catalogued as rs151099535; called by muse, mutect2, varscan2
- SCAF1 | c.894G>A p.S298= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as rs1311315672, COSV62182241; called by muse, varscan2
- SLC32A1 | c.1512C>T p.S504= | Silent (SNP) | VAF 87/245 reads (36%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.1953G>A p.P651= | Silent (SNP) | VAF 178/644 reads (28%) | catalogued as rs769023812; called by muse, mutect2, varscan2
- CC2D2B | chr10:95996245 G>A | 5'Flank (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- HMBS | c.160+85A>C | Intron (SNP) | VAF 101/316 reads (32%) | called by muse, mutect2, varscan2
